Somatic mutation profile of tumor specimen TARGET-10-PARVMR-09A (aliquot TARGET-10-PARVMR-09A-01D) from TARGET case TARGET-10-PARVMR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,811 days).
Specimen TARGET-10-PARVMR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8151791-df51-4254-ada1-aaf1fc21e672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVMR-14A (Bone Marrow Normal), aliquot TARGET-10-PARVMR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a615c85d-69b8-4362-9416-c2e5f12e83c2

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 107/113 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHMP2B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.833); catalogued as COSV55462354; called by muse, mutect2, varscan2
- MMS19 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV59135648; called by muse, mutect2, varscan2
- NCOA5 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs777887637, COSV51645044; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- PCDHB2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.02); catalogued as COSV52031592; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SHROOM4 | c.3893A>T p.E1298V | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56790870; called by muse, mutect2, varscan2
- HAP1 | c.1671G>A p.A557= (on ENST00000310778 / NM_001367460.1; = p.A505= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as rs141752762; called by muse, mutect2, varscan2
- IQSEC3 | c.2895C>T p.D965= (on ENST00000538872 / NM_001170738.2; = p.D662= on NM_015232.1) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs782285801; called by muse, mutect2, varscan2
- PTPRJ | c.2610G>A p.T870= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs143660055; called by muse, mutect2, varscan2
- SLC17A8 | c.1314C>T p.H438= | Silent (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- MUC20P1 | n.390C>T | RNA (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- OFCC1 | n.2006C>T | RNA (SNP) | VAF 4/68 reads (6%) | catalogued as rs962510213; called by muse, mutect2
